Gene-level copy-number profile of tumor specimen TCGA-CG-5724-01A from TCGA case TCGA-CG-5724, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 59.6 years (21,762 days).
Specimen TCGA-CG-5724-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.5eac06ba-b255-4b1f-94b1-c46f3784620f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-5724-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/356511f1-0fd8-41be-b097-1caa56c1a015

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 256; copy number 2: 28,054; copy number 3: 21,468; copy number 4: 5,491; copy number 5: 3,105; copy number 6: 735; copy number 7: 25; copy number 8: 209; copy number 9: 19; copy number 10: 84; copy number 11: 3; copy number 12: 125; copy number 13: 16; copy number 17: 5; copy number 20: 108; copy number 21: 29; copy number 24: 12; copy number 26: 26; copy number 27: 3; copy number 29: 28; copy number 33: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-5724-01A-11D-1599-01): tumor purity 0.65, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:71,794,232–71,837,012, 1 gene (within-gene range 0–2): NEGR1-IT1.
- chr16:78,550,739–78,553,296, 1 gene: AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,540 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:45,268,681–45,384,802, 1 gene, copy number 5 (within-gene range 4–5): AC073968.2.
- chr7:45,391,626–117,883,675, 1,335 genes, copy number 5–8 (broad region; genes not listed).
- chr8:38,600,661–47,736,306, 153 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr8:65,377,592–67,196,778, 40 genes, copy number 12: PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1.
- chr8:76,162,119–78,153,913, 16 genes, copy number 21–33: AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1.
- chr8:99,013,266–99,877,580, 1 gene, copy number 12 (within-gene range 2–12): VPS13B.
- chr8:99,527,826–109,345,954, 174 genes, copy number 9–27 (broad region; genes not listed).
- chr8:118,923,557–120,056,201, 25 genes, copy number 6–11: TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1.
- chr8:123,215,788–124,120,061, 26 genes, copy number 26 (within-gene range 2–26): MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2.
- chr8:125,091,679–128,564,679, 50 genes, copy number 20–29 (within-gene range 2–29): NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr10:78,943,328–79,355,334, 4 genes, copy number 9: ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF.
- chr10:80,247,219–80,289,658, 3 genes, copy number 8 (within-gene range 3–8): EIF5AP4, AL359195.2, MAT1A.
- chr10:80,454,166–80,646,560, 3 genes, copy number 8 (within-gene range 3–8): TSPAN14, AC021028.1, SH2D4B.
- chr10:81,136,540–81,137,335, 1 gene, copy number 8: RPA2P2.
- chr11:64,590,641–79,989,630, 593 genes, copy number 5–17 (broad region; genes not listed).
- chr12:66,767–42,459,715, 910 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr13:30,022,021–53,202,753, 435 genes, copy number 5–6 (broad region; genes not listed).
- chr13:53,258,077–53,410,880, 3 genes, copy number 6 (within-gene range 3–6): RN7SL618P, AL450423.2, AL450423.1.
- chr17:22,406,019–42,021,376, 738 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:25,099,105–25,868,225, 29 genes, copy number 5: AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2.

Autosomal genes at a single copy (total copy number 1): 214. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
